Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OI, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OI-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

PROCEDURE: SPHS

VERIFIED BY:

Dysphagia in EGD showed nodule in distal esophagus, tubulovillous mass at GEJ and fundus, and ulcerated mass at cardia. Biopsies showed invasive adenocarcinoma.

PROCEDURE: SPGD

1CB-0-3
adenocarcinoma, Nos 8140/3
Site: esophagus, distal third
C15.5

fw
10/9/12

1. "Distal esophagus and proximal stomach"

Received in a large container of formalin is a previously opened 17.2 cm segment of distal esophagus and proximal stomach. This portion is stapled at both margins. The attached perigastric fat is focally nodular and focally hemorrhagic. The adventitia and the gastric serosa are focally firm and puckered. Arising in the esophageal mucosa, crossing over the esophagogastric junction and extending into the gastric mucosa is a 7.3 x 4.6 cm centrally ulcerated mass. The borders of this large mass are raised and rolled. The proximal end of this mass is 7.8 cm from the proximal margin and the distal extension comes to within 2.5 cm of the gastric margin. The cut surface is yellow-gray to tan, focally hyperemic with a maximum thickness of 2.4 cm. The large mass extends through the muscular wall and involves the tightly adherent perigastric fat. The adventitia is inked green and the gastric serosa is inked black. The cut surface shows the mass abutting the inked margins. Multiple lymph node candidates are retrieved from the perigastric fat up to 2.9 cm in greatest dimensions. Some of the larger lymph node candidates have cut surfaces that are gray-white and yellow-tan.

1A-C. Trisected full thickness section from proximal to distal.

1D-E. Trisected full thickness section from proximal to distal.

1F. Maximum thickness at mid portion.

1G. Eleven whole lymph node candidates.

1H. Eight whole lymph node candidates.

1I. Two lymph node candidates (one inked and bisected).

1J-K. Sectioned lymph node candidate.

1L-M. Sectioned lymph node candidate. Fat retained.

2. "Cervical esophageal margin"

Received in a small container of formalin is a 1 cm segment of esophagus that is stapled at one margin and opened at the opposing margin. The adventitia is focally hemorrhagic, and the mucosa is unremarkable.

2A. Cervical esophageal margin.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M

PROCEDURE: SPMI

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA,
CARCINOMA (RESECTION SPECIMENS):

LOCATION: Gastroesophageal junction, straddling the junction.

SIZE: 7.3 cm.

TYPE OF CARCINOMA: Adenocarcinoma, not arising in Barrett's mucosa.

DEPTH OF INVASION: Adventitia.

HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY? No.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 8/20.

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: No.

pT3 N3

PROCEDURE: SPDX

1-2. Distal esophagus and proximal stomach, resections: Invasive, moderately-differentiated adenocarcinoma (7.3 cm), extending into the adventitia. Margins free. Eight of twenty lymph nodes positive for metastatic adenocarcinoma (8/20). Please see TEMPLATE for details.

I, [redacted] the signing staff pathologist, have personally examined and interpreted the slides from this case.

dx/px Discrepancy		/
2nd dx/px Discrepancy History		/
Discrepancy Primary Noted		/

Source: NCI Genomic Data Commons file 136b74e1-9601-4983-a84a-3543b79988a7 (TCGA-L5-A4OI.D04FEEE2-5739-41E6-BF76-7412E184F299.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).